Gene-level copy-number profile of tumor specimen HTMCP-03-06-02333-01A from CGCI case HTMCP-03-06-02333, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA1; Tumor grade: G1; Age at diagnosis: 47.6 years (17,396 days).
Specimen HTMCP-03-06-02333-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 259aaa60-f677-42a3-83ff-1bc478aae732.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02333-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/b3b9c7f0-175d-4c61-9eaa-584fb19044d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 60; copy number 2: 40,378; copy number 3: 15,326; copy number 4: 2,501; copy number 5: 46; copy number 6: 8; copy number 7: 31; copy number 9: 13; copy number 10: 2; copy number 12: 26; copy number 13: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 131 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,525,805–27,530,561, 1 gene, copy number 5: BX293535.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 9: TRGC2.
- chr7:38,257,879–38,330,935, 12 genes, copy number 9: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr7:142,626,649–142,802,748, 36 genes, copy number 5: TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr9:60,914,407–61,642,494, 15 genes, copy number 5–13: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr14:21,990,496–22,499,749, 65 genes, copy number 5–12 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 12: TRAC.

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
